Somatic mutation profile of tumor specimen ALCH-AE4S-TTR1-A (aliquot ALCH-AE4S-TTR1-A-1-0-D-A799-36) from ALCHEMIST case ALCH-AE4S, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.7 years (21,090 days).
Specimen ALCH-AE4S-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e68da7ac-271b-46ff-817c-808f05fdd687.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AE4S-NB1-B (Blood Derived Normal), aliquot ALCH-AE4S-NB1-B-1-0-D-A678-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/188859b2-f89a-4b8f-8183-841745b6fa5f

The open-access MAF lists 522 somatic variants for this specimen: 387 protein-altering or splice-affecting, 89 silent, 46 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 339, Silent 89, Intron 25, Nonsense Mutation 19, Splice Site 10, Frame Shift Del 10, RNA 7, 5'UTR 4, 5'Flank 4, Splice Region 3, 3'Flank 3, Frame Shift Ins 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.247C>T p.H83Y | Missense Mutation (SNP) | VAF 32/180 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs121913385, CM053801, CM056557, COSV58682852, COSV58685578, COSV58690009; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- DIS3 | c.1462G>T p.D488Y | Missense Mutation (SNP) | VAF 27/378 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705661, COSV66706270; called by muse, mutect2
- RYR1 | c.7373G>T p.R2458L | Missense Mutation (SNP) | VAF 45/261 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs121918594, CM118674, CM981783, COSV62093719; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.643A>G p.S215G | Missense Mutation (SNP) | VAF 100/394 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs886039484, CD1511147, COSV52675946, COSV52689203, COSV52876251, COSV53707934; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA13 | c.8865G>T p.L2955F | Missense Mutation (SNP) | VAF 39/276 reads (14%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.906); catalogued as COSV101446717; called by muse, mutect2, varscan2
- ABCG8 | c.538T>C p.S180P | Missense Mutation (SNP) | VAF 55/297 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as rs868807877; called by muse, mutect2, varscan2
- ACE2 | c.583+1G>C p.X195_splice | Splice Site (SNP) | VAF 13/72 reads (18%) | catalogued as COSV99382616; called by muse, mutect2
- ACSM1 | c.1168G>A p.G390R | Missense Mutation (SNP) | VAF 14/390 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs866290559, COSV99533066; called by muse, mutect2
- ADAMTS10 | c.1177G>T p.E393* | Nonsense Mutation (SNP) | VAF 55/246 reads (22%) | catalogued as COSV54354398; called by muse, mutect2, varscan2
- ADAMTS20 | c.4147G>T p.V1383L | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67126000; called by muse, mutect2, varscan2
- ADCY2 | c.220G>T p.D74Y | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.492); catalogued as COSV57900020; called by muse, mutect2
- ALB | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 114/650 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs58624704, COSV55739298; called by muse, mutect2, varscan2
- AMPH | c.1528G>A p.A510T | Missense Mutation (SNP) | VAF 42/539 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs574824661, COSV100343130, COSV57742984; called by muse, mutect2
- ANKRD27 | c.550A>G p.K184E | Missense Mutation (SNP) | VAF 34/216 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV60131454; called by muse, mutect2, varscan2
- ARAP2 | c.3427G>T p.G1143C | Missense Mutation (SNP) | VAF 36/218 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100394995; called by muse, mutect2, varscan2
- ARHGAP33 | c.884C>T p.S295F | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1182745854; called by muse, mutect2, varscan2
- ARMCX5 | c.1045C>T p.H349Y | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.92); catalogued as rs866416226; called by muse, mutect2, varscan2
- ASB10 | c.730C>A p.R244S (on ENST00000420175 / NM_001142459.2; = p.R229S on NM_080871.4) | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); catalogued as COSV51997743, COSV99318781; called by muse, mutect2, varscan2
- ASTN1 | c.1770C>A p.S590R | Missense Mutation (SNP) | VAF 38/405 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.286); catalogued as rs1457570004; called by muse, mutect2
- BRINP1 | c.1270C>A p.R424S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.972); catalogued as rs758808562, COSV56295225; called by mutect2, varscan2
- C12orf40 | c.1634A>G p.D545G | Missense Mutation (SNP) | VAF 50/576 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV61136694; called by muse, mutect2
- C8B | c.534G>T p.G178= | Splice Region (SNP) | VAF 50/515 reads (10%) | catalogued as COSV64777626; called by muse, mutect2
- CCL26 | c.230G>A p.R77K | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs782624721; called by muse, mutect2
- CDC14C | c.347C>G p.P116R (on ENST00000428251; = p.P9R on NM_152627.3) | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs1213774009; called by muse, mutect2, varscan2
- CDH12 | c.1459C>A p.P487T | Missense Mutation (SNP) | VAF 33/368 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101203210; called by muse, mutect2
- CDH2 | c.665C>T p.T222I | Missense Mutation (SNP) | VAF 11/189 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1257768241; called by muse, mutect2
- CDK5 | c.467G>T p.R156L | Missense Mutation (SNP) | VAF 20/306 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as COSV99876744; called by muse, mutect2
- CDX4 | c.275C>A p.T92K | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.537); catalogued as rs749168322; called by muse, varscan2
- CEP95 | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as COSV73609715; called by muse, mutect2
- CFAP47 | c.847del p.V283Wfs*25 | Frame Shift Del (DEL) | VAF 24/122 reads (20%) | catalogued as COSV99935278; called by mutect2, pindel*, varscan2
- CHN1 | c.792G>C p.K264N | Missense Mutation (SNP) | VAF 65/414 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.821); catalogued as COSV55033142; called by muse, mutect2, varscan2
- CHRM3 | c.666C>A p.F222L | Missense Mutation (SNP) | VAF 51/640 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as COSV55087727; called by muse, mutect2
- CNTNAP2 | c.3920C>T p.A1307V | Missense Mutation (SNP) | VAF 41/371 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.492); catalogued as rs149487593; ClinVar: uncertain significance; called by muse, varscan2
- COL11A1 | c.311C>G p.T104R | Missense Mutation (SNP) | VAF 36/312 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62182534; called by muse, varscan2
- COL14A1 | c.3931A>T p.K1311* | Nonsense Mutation (SNP) | VAF 18/264 reads (7%) | catalogued as COSV52865550; called by muse, mutect2
- COL4A5 | c.1507G>T p.G503C | Missense Mutation (SNP) | VAF 43/159 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM098946; called by muse, mutect2, varscan2
- CSMD3 | c.5816G>T p.C1939F (on ENST00000297405 / NM_001363185.1; = p.C1835F on NM_052900.3) | Missense Mutation (SNP) | VAF 103/769 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52145731; called by muse, mutect2, varscan2
- CTNND2 | c.416del p.P139Hfs*193 | Frame Shift Del (DEL) | VAF 34/264 reads (13%) | catalogued as COSV58871225; called by mutect2, pindel, varscan2
- CUX2 | c.3792G>T p.E1264D | Missense Mutation (SNP) | VAF 37/193 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.018); catalogued as COSV55651396; called by muse, mutect2, varscan2
- CXCR1 | c.85C>A p.P29T | Missense Mutation (SNP) | VAF 44/346 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs371028807; called by muse, mutect2
- DEAF1 | c.69_98del p.A24_A33del | In Frame Del (DEL) | VAF 9/73 reads (12%) | catalogued as rs754135731; called by mutect2, varscan2*
- DFFB | c.768G>T p.W256C | Missense Mutation (SNP) | VAF 17/190 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs960435824; called by muse, mutect2
- DGKB | c.2406C>A p.S802R | Missense Mutation (SNP) | VAF 40/596 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as COSV99337672; called by muse, mutect2
- DLG2 | c.1237G>T p.V413F | Missense Mutation (SNP) | VAF 81/439 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as rs200531656; called by muse, mutect2, varscan2
- DMD | c.4344+1G>T p.X1448_splice | Splice Site (SNP) | VAF 57/321 reads (18%) | catalogued as rs1172744225; called by muse, mutect2, varscan2
- DST | c.22301G>A p.R7434Q (on ENST00000361203 / NM_001374722.1; = p.R5144Q on NM_015548.5) | Missense Mutation (SNP) | VAF 54/193 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs761116868; called by muse, mutect2, varscan2
- DTL | c.1216G>A p.V406M | Missense Mutation (SNP) | VAF 112/605 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); catalogued as rs1281584289, COSV100877202; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1677G>C p.L559F (on ENST00000361735 / NM_015935.5; = p.L473F on NM_014955.3) | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV100676023; called by muse, mutect2
- EFCAB6 | c.2090G>T p.G697V | Missense Mutation (SNP) | VAF 50/189 reads (26%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.841); catalogued as rs763425686; called by muse, mutect2, varscan2
- ENPP4 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 22/364 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.095); catalogued as COSV58089343; called by muse, mutect2
- EPG5 | c.1637G>T p.G546V | Missense Mutation (SNP) | VAF 50/298 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.022); catalogued as COSV56357296; called by muse, mutect2, varscan2
- EPPK1 | c.4973G>A p.G1658E | Missense Mutation (SNP) | VAF 36/281 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs1411621635, COSV73261435; called by muse, mutect2, varscan2
- ERC2 | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 66/232 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs758640784, COSV99884332; called by muse, mutect2, varscan2
- F2RL2 | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 58/259 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56972353; called by muse, mutect2, varscan2
- GBP4 | c.1019C>A p.A340E | Missense Mutation (SNP) | VAF 20/223 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.234); catalogued as COSV63252809; called by muse, mutect2, varscan2
- GLDN | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 21/208 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.294); catalogued as rs1033782161; called by muse, mutect2, varscan2
- GPR158 | c.3085G>A p.V1029I | Missense Mutation (SNP) | VAF 52/599 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.3); catalogued as rs770315576; called by muse, mutect2
- GRIP1 | c.2023G>C p.E675Q (on ENST00000359742 / NM_001379345.1; = p.E623Q on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/370 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as COSV54033512; called by muse, mutect2
- H1-2 | c.482C>A p.P161Q | Missense Mutation (SNP) | VAF 23/288 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100642237; called by muse, mutect2
- HIP1 | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.082); catalogued as rs1554523975; called by muse, mutect2, varscan2
- HMGN5 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT tolerated (0.79); PolyPhen benign (0.023); catalogued as COSV63916674; called by muse, mutect2, varscan2
- HUWE1 | c.4976C>T p.T1659M | Missense Mutation (SNP) | VAF 23/247 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.962); catalogued as rs1556971958, COSV53366811; called by muse, mutect2
- IBA57 | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs951345105, COSV100812748; called by muse, mutect2
- IGDCC4 | c.3632C>T p.P1211L | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs560887461, COSV61537226; called by muse, mutect2, varscan2
- IGHA2 | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 58/340 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.844); catalogued as rs1357557134; called by muse, mutect2, varscan2
- IL17RC | c.1490C>T p.T497M (on ENST00000295981 / NM_153461.4; = p.T411M on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs747269828; called by muse, mutect2, varscan2
- INF2 | c.2050G>A p.E684K | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770166116; called by muse, mutect2
- IRGQ | c.1792C>T p.H598Y | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT tolerated (1); PolyPhen probably damaging (0.991); catalogued as COSV60671008; called by muse, mutect2, varscan2
- IRX1 | c.328G>T p.A110S | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.346); catalogued as COSV57358951; called by muse, mutect2, varscan2
- JAML | c.355C>G p.R119G (on ENST00000356289 / NM_001098526.2; = p.R109G on NM_153206.3) | Missense Mutation (SNP) | VAF 80/649 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV52629872; called by muse, mutect2, varscan2
- KCNJ12 | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59163004; called by muse, mutect2, varscan2
- KCNJ12 | c.836C>G p.P279R | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59162471; called by muse, mutect2, varscan2
- KLHL36 | c.1352G>A p.G451D | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.811); catalogued as rs942543634; called by muse, mutect2
- KLHL7 | c.1530G>T p.M510I (on ENST00000339077 / NM_001031710.3; = p.M462I on NM_018846.5) | Missense Mutation (SNP) | VAF 41/292 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV100177565; called by muse, mutect2, varscan2
- LNX1 | c.1040C>G p.P347R (on ENST00000263925 / NM_001126328.3; = p.P251R on NM_032622.2) | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771769366, COSV55782286; called by muse, mutect2, varscan2
- LRP1B | c.7780G>T p.V2594F | Missense Mutation (SNP) | VAF 36/278 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.119); catalogued as rs1363852530, COSV67244458; called by muse, mutect2, varscan2
- LRRC7 | c.4400G>T p.R1467L (on ENST00000651989 / NM_001370785.2; = p.R1387L on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/404 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.1); catalogued as COSV99227906; called by muse, mutect2, varscan2
- LRRIQ1 | c.1695G>T p.E565D | Missense Mutation (SNP) | VAF 33/235 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV101280737; called by muse, mutect2, varscan2
- MAGEC2 | c.834G>T p.W278C | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as COSV99909764; called by muse, mutect2, varscan2
- MAP4K5 | c.585C>A p.Y195* | Nonsense Mutation (SNP) | VAF 44/492 reads (9%) | catalogued as COSV50152924; called by muse, mutect2
- MMEL1 | c.337G>T p.D113Y | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV56519258; called by muse, mutect2, varscan2
- MMRN1 | c.2906C>A p.P969Q | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV53338104, COSV99306646; called by muse, mutect2, varscan2
- MTUS2 | c.1511C>A p.T504K | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.167); catalogued as rs758637752; called by muse, mutect2, varscan2
- MYO7B | c.1152G>T p.R384S | Missense Mutation (SNP) | VAF 46/260 reads (18%) | SIFT tolerated (0.77); PolyPhen benign (0.383); catalogued as COSV101268308; called by muse, mutect2, varscan2
- NALCN | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 21/253 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as COSV51915483; called by muse, mutect2
- NAV2 | c.2556G>T p.R852S (on ENST00000396087 / NM_001244963.2; = p.R829S on NM_145117.5) | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.37); catalogued as COSV62323162; called by muse, mutect2, varscan2
- NIFK | c.349G>T p.E117* | Nonsense Mutation (SNP) | VAF 35/194 reads (18%) | catalogued as COSV53534316; called by muse, mutect2, varscan2
- NTNG1 | c.466C>A p.R156S | Missense Mutation (SNP) | VAF 39/314 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53964408; called by muse, mutect2, varscan2
- OCA2 | c.2158C>A p.R720S | Missense Mutation (SNP) | VAF 31/299 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as CM992196; called by muse, mutect2, varscan2
- OR2C3 | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 40/543 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs747697715; called by muse, mutect2
- OR2G3 | c.70G>T p.E24* | Nonsense Mutation (SNP) | VAF 20/200 reads (10%) | catalogued as COSV60682389; called by muse, mutect2, varscan2
- OR2J3 | c.220C>A p.L74I | Missense Mutation (SNP) | VAF 60/209 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.214); catalogued as COSV65849157; called by muse, mutect2, varscan2
- OR2T33 | c.602G>T p.C201F | Missense Mutation (SNP) | VAF 39/444 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58817995; called by muse, mutect2, varscan2
- OR4S2 | c.748G>T p.G250C | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs757570101, COSV56748350; called by muse, mutect2, varscan2
- OR51L1 | c.94C>A p.L32I | Missense Mutation (SNP) | VAF 38/291 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.134); catalogued as COSV58624743, COSV58625749; called by muse, mutect2, varscan2
- OTOF | c.3332C>A p.P1111Q (on ENST00000272371 / NM_194248.3; = p.P364Q on NM_004802.4) | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs141972928; called by muse, mutect2, varscan2
- OVCH1 | c.1564C>A p.Q522K | Missense Mutation (SNP) | VAF 24/201 reads (12%) | SIFT tolerated (0.89); PolyPhen benign (0.01); catalogued as COSV58963182; called by muse, mutect2, varscan2
- P2RY6 | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs375926613; called by muse, mutect2, varscan2
- PAPSS2 | c.1651C>T p.R551* | Nonsense Mutation (SNP) | VAF 34/343 reads (10%) | catalogued as rs138386772, COSV100753537; called by muse, mutect2, varscan2
- PARD3B | c.3382C>T p.R1128C (on ENST00000406610 / NM_001302769.2; = p.R1059C on NM_057177.7) | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1174053056; called by muse, mutect2, varscan2
- PCDH15 | c.4095G>T p.K1365N | Missense Mutation (SNP) | VAF 190/722 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV57267577, COSV57339717; called by muse, mutect2, varscan2
- PCDH17 | c.290G>C p.R97P | Missense Mutation (SNP) | VAF 24/316 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV64975942; called by muse, mutect2
- PCDHA2 | c.1072C>G p.P358A | Missense Mutation (SNP) | VAF 63/394 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.595); catalogued as COSV100973801, COSV65366979; called by muse, mutect2, varscan2
- PCDHA8 | c.1170G>T p.M390I | Missense Mutation (SNP) | VAF 75/257 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV65340421, COSV65341310; called by muse, mutect2, varscan2
- PCDHA8 | c.1366G>A p.A456T | Missense Mutation (SNP) | VAF 78/209 reads (37%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.01); catalogued as COSV65336409; called by muse, mutect2, varscan2
- PCDHB4 | c.2041C>A p.Q681K | Missense Mutation (SNP) | VAF 25/231 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.017); catalogued as COSV99522466; called by muse, mutect2, varscan2
- PCDHGA1 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.031); catalogued as COSV65298723, COSV65299069; called by muse, mutect2, varscan2
- PCF11 | c.2498G>C p.R833P | Missense Mutation (SNP) | VAF 75/454 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as COSV53529547, COSV53530301; called by muse, mutect2, varscan2
- PDE6C | c.467C>A p.P156Q | Missense Mutation (SNP) | VAF 162/668 reads (24%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.895); catalogued as COSV101008622, COSV65116401; called by muse, mutect2, varscan2
- PKHD1 | c.11249C>T p.S3750L | Missense Mutation (SNP) | VAF 48/486 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV64399068; called by muse, mutect2
- PLAAT1 | c.818A>G p.Y273C (on ENST00000650797; = p.Y168C on NM_020386.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/200 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as rs750466387; called by muse, mutect2
- PTPRB | c.570G>T p.E190D | Missense Mutation (SNP) | VAF 93/494 reads (19%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as rs112249725; called by muse, mutect2, varscan2
- PTPRZ1 | c.2863G>T p.G955C | Missense Mutation (SNP) | VAF 81/300 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.671); catalogued as rs763354591, COSV66444072; called by muse, mutect2, varscan2
- RADIL | c.1619C>A p.S540* | Nonsense Mutation (SNP) | VAF 9/77 reads (12%) | catalogued as COSV68199476; called by muse, mutect2, varscan2
- RGS8 | c.310A>G p.K104E (on ENST00000367556 / NM_001369564.2; = p.K122E on NM_033345.3) | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as COSV51116479; called by muse, mutect2, varscan2
- RYR2 | c.1634G>T p.R545L | Missense Mutation (SNP) | VAF 42/643 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV63694226; called by muse, mutect2
- SIPA1L2 | c.2969G>A p.R990H | Missense Mutation (SNP) | VAF 56/570 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1301775123, COSV53394039; called by muse, mutect2
- SKOR1 | c.2189G>T p.R730L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.061); catalogued as rs1215580037; called by muse, mutect2, varscan2
- SLC24A4 | c.1094C>A p.P365Q | Missense Mutation (SNP) | VAF 47/262 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.348); catalogued as COSV54117014, COSV54118409; called by muse, mutect2, varscan2
- SLC39A10 | c.209G>T p.R70L | Missense Mutation (SNP) | VAF 39/286 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.402); catalogued as COSV62767732; called by muse, mutect2, varscan2
- SLC9A2 | c.1876G>T p.A626S | Missense Mutation (SNP) | VAF 44/498 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.033); catalogued as COSV99029357; called by muse, mutect2
- SLC9A2 | c.1877C>T p.A626V | Missense Mutation (SNP) | VAF 44/502 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.033); catalogued as rs1393376411, COSV52131809; called by muse, mutect2
- SORBS2 | c.1337C>T p.A446V | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as rs773054747; called by muse, mutect2
- SOX5 | c.58G>T p.A20S | Missense Mutation (SNP) | VAF 39/175 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.265); catalogued as rs746451995; called by muse, mutect2, varscan2
- STPG2 | c.1198G>T p.G400W | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV54785641; called by muse, mutect2, varscan2
- STYXL2 | c.2438G>T p.R813I | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as COSV54805980; called by muse, mutect2, varscan2
- SUPT20H | c.173G>A p.R58K (on ENST00000350612 / NM_001014286.3; = p.R59K on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/353 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.347); catalogued as rs1485719287, COSV62246766, COSV62250094; called by muse, mutect2, varscan2
- TECRL | c.535C>A p.R179S | Missense Mutation (SNP) | VAF 43/168 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.09); catalogued as COSV67090572; called by muse, mutect2, varscan2
- TEX47 | c.278C>A p.P93H | Missense Mutation (SNP) | VAF 19/271 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1226394222; called by muse, mutect2
- TGIF2LX | c.492G>T p.K164N | Missense Mutation (SNP) | VAF 57/269 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.045); catalogued as COSV52213391, COSV52215223; called by muse, mutect2, varscan2
- TIGD2 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 20/317 reads (6%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); catalogued as rs765853331; called by muse, mutect2
- TMEM117 | c.285G>T p.L95F | Missense Mutation (SNP) | VAF 21/244 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.034); catalogued as COSV99862874; called by muse, mutect2
- TRIM51 | c.443G>T p.W148L | Missense Mutation (SNP) | VAF 40/344 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.387); catalogued as COSV55266874, COSV99792761; called by muse, mutect2, varscan2
- TTC25 | c.1886G>A p.R629K | Missense Mutation (SNP) | VAF 73/998 reads (7%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.005); catalogued as rs1237605918; called by muse, mutect2
- TYK2 | c.2110G>T p.G704C | Missense Mutation (SNP) | VAF 52/216 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV99314065; called by muse, mutect2, varscan2
- UNC80 | c.1286C>G p.S429C | Missense Mutation (SNP) | VAF 45/392 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.518); catalogued as rs1228713310; called by muse, mutect2, varscan2
- UPF2 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV100707426; called by muse, mutect2, varscan2
- UPK3B | c.443C>T p.P148L (on ENST00000257632; = p.P93L on NM_001347684.2) | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.661); catalogued as rs765374716, COSV57536652; called by muse, mutect2, varscan2
- WBP1L | c.868C>T p.R290W | Missense Mutation (SNP) | VAF 14/175 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs201482384, COSV64009958; called by muse, mutect2
- WDR64 | c.2980C>A p.P994T | Missense Mutation (SNP) | VAF 34/221 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.058); catalogued as rs1334367822, COSV63800465; called by muse, mutect2, varscan2
- WFDC1 | c.112G>T p.A38S | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as rs766149943, COSV54745719; called by muse, mutect2, varscan2
- ZDHHC7 | c.103G>A p.V35M | Missense Mutation (SNP) | VAF 46/356 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs753278313; called by muse, mutect2, varscan2
- ZDHHC8 | c.2243C>T p.T748M | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as rs1397959951, COSV57713503; called by muse, mutect2, varscan2
- ZEB1 | c.1097G>T p.C366F | Missense Mutation (SNP) | VAF 110/362 reads (30%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.802); catalogued as COSV100314223; called by muse, mutect2, varscan2
- ZKSCAN3 | c.302A>G p.N101S | Missense Mutation (SNP) | VAF 77/368 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs1264203811; called by muse, mutect2, varscan2
- ZNF658 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 86/663 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs375581570; called by muse, mutect2, varscan2
- ZNF736 | c.141C>G p.I47M | Missense Mutation (SNP) | VAF 46/614 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as rs1299952507; called by muse, mutect2
- ABCA8 | c.2110G>T p.G704* | Nonsense Mutation (SNP) | VAF 18/296 reads (6%) | called by muse, mutect2
- ACAN | c.2119C>T p.P707S | Missense Mutation (SNP) | VAF 55/250 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ACAN | c.2477C>A p.S826Y | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- ADAMTS14 | c.616G>C p.V206L | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- ADCY4 | c.2291G>T p.W764L | Missense Mutation (SNP) | VAF 38/174 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRA3 | c.77C>A p.A26E | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- ADH7 | c.851T>A p.L284H | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- AGAP1 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 11/62 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by mutect2, varscan2
- AHSA1 | c.47G>T p.R16L | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- ANKRD18B | c.307A>G p.T103A | Missense Mutation (SNP) | VAF 53/199 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- ANOS1 | c.519A>T p.Q173H | Missense Mutation (SNP) | VAF 58/280 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APBB1IP | c.961G>C p.E321Q | Missense Mutation (SNP) | VAF 66/406 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- ARAP2 | c.3426T>A p.Y1142* | Nonsense Mutation (SNP) | VAF 37/219 reads (17%) | called by mutect2, varscan2
- ATF6B | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 33/293 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- AXDND1 | c.2561G>T p.S854I | Missense Mutation (SNP) | VAF 38/230 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- B3GALNT2 | c.684A>T p.Q228H | Missense Mutation (SNP) | VAF 46/759 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2
- BCL6 | c.1907G>T p.G636V | Missense Mutation (SNP) | VAF 57/404 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BRINP3 | c.995T>A p.M332K | Missense Mutation (SNP) | VAF 35/301 reads (12%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- BTBD18 | c.335C>A p.A112D | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BTN1A1 | c.1157C>A p.P386H | Missense Mutation (SNP) | VAF 117/412 reads (28%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- C6 | c.787C>A p.H263N | Missense Mutation (SNP) | VAF 178/923 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- CARD8 | c.378G>T p.E126D (on ENST00000651546 / NM_001184900.3; = p.E76D on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/552 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.018); called by muse, mutect2
- CBX2 | c.837G>T p.Q279H | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- CCDC154 | c.1702G>A p.E568K | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- CCDC154 | c.1441G>C p.E481Q | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- CDH10 | c.1817C>T p.P606L | Missense Mutation (SNP) | VAF 34/353 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.38); called by muse, mutect2
- CDH8 | c.1756C>A p.L586M | Missense Mutation (SNP) | VAF 158/992 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- CELSR1 | c.6054del p.T2019Pfs*32 | Frame Shift Del (DEL) | VAF 34/160 reads (21%) | called by mutect2, pindel, varscan2
- CFAP54 | c.6332T>A p.L2111Q | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CFH | c.1484G>T p.G495V | Missense Mutation (SNP) | VAF 159/878 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CHPF2 | c.580G>T p.A194S | Missense Mutation (SNP) | VAF 75/334 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CKAP2 | c.682G>T p.V228L (on ENST00000378037 / NM_001098525.2; = p.V227L on NM_018204.5) | Missense Mutation (SNP) | VAF 37/305 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CLVS1 | c.739C>G p.R247G | Missense Mutation (SNP) | VAF 66/284 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CMKLR1 | c.815G>T p.C272F (on ENST00000312143 / NM_001142344.2; = p.C270F on NM_004072.3) | Missense Mutation (SNP) | VAF 40/562 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CNTNAP2 | c.2786G>T p.G929V | Missense Mutation (SNP) | VAF 38/502 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.828); called by muse, mutect2
- CNTNAP5 | c.1128C>G p.S376R | Missense Mutation (SNP) | VAF 50/300 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- COL11A2 | c.4595G>C p.G1532A (on ENST00000341947 / NM_080680.3; = p.G1425A on NM_080679.2) | Missense Mutation (SNP) | VAF 41/402 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- COL6A5 | c.5015T>A p.F1672Y | Missense Mutation (SNP) | VAF 87/418 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- COL6A6 | c.2113del p.L705* | Frame Shift Del (DEL) | VAF 53/243 reads (22%) | called by mutect2, pindel, varscan2
- CPT1A | c.1151C>G p.T384S | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- CREBBP | c.925A>T p.T309S | Missense Mutation (SNP) | VAF 122/663 reads (18%) | SIFT tolerated (0.78); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CSF1R | c.994C>A p.Q332K | Missense Mutation (SNP) | VAF 30/211 reads (14%) | SIFT tolerated (0.99); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- CSMD1 | c.5294G>T p.R1765L (on ENST00000520002; = p.R1764L on NM_033225.6) | Missense Mutation (SNP) | VAF 62/304 reads (20%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CSMD3 | c.9913A>T p.K3305* (on ENST00000297405 / NM_001363185.1; = p.K3136* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 169/864 reads (20%) | called by muse, mutect2, varscan2
- CTSC | c.976G>T p.G326C | Missense Mutation (SNP) | VAF 192/563 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CWC27 | c.1369A>T p.R457W | Missense Mutation (SNP) | VAF 37/239 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CWC27 | c.1370G>A p.R457K | Missense Mutation (SNP) | VAF 38/239 reads (16%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- DCAF12L1 | c.958G>T p.V320L | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCDC1 | c.4486C>A p.Q1496K (on ENST00000597505 / NM_001367979.1; = p.Q603K on NM_020869.3) | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCLK3 | c.1585+1G>T p.X529_splice | Splice Site (SNP) | VAF 51/255 reads (20%) | called by muse, mutect2, varscan2
- DFFB | c.767G>T p.W256L | Missense Mutation (SNP) | VAF 20/189 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH5 | c.13490A>T p.Q4497L | Missense Mutation (SNP) | VAF 86/480 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DOCK1 | c.3388A>T p.T1130S | Missense Mutation (SNP) | VAF 128/533 reads (24%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- DPYS | c.63G>C p.E21D | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DUSP15 | c.100A>T p.I34F (on ENST00000278979 / NM_001320479.1; = p.I37F on NM_080611.4) | Missense Mutation (SNP) | VAF 78/482 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1777G>T p.G593* | Nonsense Mutation (SNP) | VAF 26/342 reads (8%) | called by muse, mutect2
- ENPP1 | c.447C>A p.C149* | Nonsense Mutation (SNP) | VAF 105/596 reads (18%) | called by muse, mutect2, varscan2
- EPS15L1 | c.2164+1G>A p.X722_splice | Splice Site (SNP) | VAF 34/466 reads (7%) | called by muse, mutect2
- ERCC3 | c.1037A>T p.K346M | Missense Mutation (SNP) | VAF 6/117 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ESYT2 | c.2701G>T p.A901S (on ENST00000613624; = p.A825S on NM_020728.3) | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT tolerated (0.92); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- F12 | c.1018+2T>A p.X340_splice | Splice Site (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2, varscan2
- FAM135B | c.2678C>A p.T893N | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); called by muse, mutect2
- FAM171A1 | c.2034G>T p.L678F | Missense Mutation (SNP) | VAF 104/298 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- FAM181B | c.266G>T p.R89L | Missense Mutation (SNP) | VAF 47/202 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- FAT4 | c.1864T>A p.L622I | Missense Mutation (SNP) | VAF 11/189 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.243); called by muse, mutect2
- FBXL13 | c.152G>T p.R51I | Missense Mutation (SNP) | VAF 21/400 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); called by muse, mutect2
- FPR1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- FSIP2 | c.15340C>A p.P5114T | Missense Mutation (SNP) | VAF 23/219 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- FSTL1 | c.193G>T p.V65L | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GABBR2 | c.2728G>T p.V910L | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- GALNT16 | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 50/245 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GDAP1L1 | c.887C>A p.P296H | Missense Mutation (SNP) | VAF 20/290 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- GFAP | c.1263G>C p.Q421H | Missense Mutation (SNP) | VAF 28/535 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); called by muse, mutect2
- GNB5 | c.433A>T p.M145L (on ENST00000261837 / NM_016194.4; = p.M103L on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.007); called by mutect2, varscan2
- GPCPD1 | c.1700G>T p.R567I | Missense Mutation (SNP) | VAF 31/297 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- HAVCR2 | c.134del p.P45Qfs*31 | Frame Shift Del (DEL) | VAF 17/109 reads (16%) | called by mutect2, pindel, varscan2
- HOXB2 | c.1054G>T p.D352Y | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HRNR | c.1551T>G p.Y517* | Nonsense Mutation (SNP) | VAF 36/810 reads (4%) | called by muse, mutect2
- HSF5 | c.1444C>A p.Q482K | Missense Mutation (SNP) | VAF 48/228 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- HTR4 | c.94G>T p.A32S | Missense Mutation (SNP) | VAF 38/238 reads (16%) | PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- IGHV3-20 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 50/406 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- INSC | c.1634G>T p.G545V | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- INSR | c.1461G>T p.K487N | Missense Mutation (SNP) | VAF 44/214 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- IQCA1 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 24/222 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- IRX4 | c.195C>A p.N65K | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.683); called by muse, mutect2
- ITGA2B | c.1567G>T p.G523* | Nonsense Mutation (SNP) | VAF 127/737 reads (17%) | called by muse, mutect2, varscan2
- KCNH4 | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCP | c.3032del p.P1011Lfs*14 (on ENST00000620378; = p.P1071Lfs*14 on NM_001366122.1) | Frame Shift Del (DEL) | VAF 16/68 reads (24%) | called by mutect2, pindel, varscan2
- KDR | c.3660C>A p.I1220= | Splice Region (SNP) | VAF 27/125 reads (22%) | called by muse, mutect2, varscan2
- KEAP1 | c.200T>A p.M67K | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- KIF1A | c.776del p.G259Efs*17 | Frame Shift Del (DEL) | VAF 13/100 reads (13%) | called by mutect2, pindel, varscan2
- KLHL32 | c.1846A>T p.R616W | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- KLKB1 | c.1899G>C p.Q633H | Missense Mutation (SNP) | VAF 38/534 reads (7%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.173); called by muse, mutect2
- KMO | c.222+1G>T p.X74_splice | Splice Site (SNP) | VAF 51/292 reads (17%) | called by muse, mutect2, varscan2
- KRT14 | c.771G>T p.M257I | Missense Mutation (SNP) | VAF 41/316 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.241); called by muse, mutect2
- KRT14 | c.769A>T p.M257L | Missense Mutation (SNP) | VAF 40/310 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.09); called by muse, mutect2
- KRT38 | c.994G>T p.V332L | Missense Mutation (SNP) | VAF 50/336 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.34); called by muse, varscan2
- LAMC3 | c.3511A>T p.T1171S | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.011); called by muse, mutect2
- LCE3D | c.13C>A p.Q5K | Missense Mutation (SNP) | VAF 20/292 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- LEPR | c.3401G>T p.S1134I | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LONP2 | c.1768G>T p.D590Y | Missense Mutation (SNP) | VAF 38/281 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- LOXHD1 | c.4530G>T p.T1510= | Splice Region (SNP) | VAF 27/119 reads (23%) | called by muse, mutect2, varscan2
- LRFN5 | c.144C>A p.N48K | Missense Mutation (SNP) | VAF 67/358 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- LRRC37A3 | c.350G>C p.G117A | Missense Mutation (SNP) | VAF 32/268 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.057); called by mutect2, varscan2
- LRRC71 | c.1632del p.I545Sfs*24 | Frame Shift Del (DEL) | VAF 27/154 reads (18%) | called by mutect2, pindel, varscan2
- LYPD2 | c.314C>A p.P105H | Missense Mutation (SNP) | VAF 44/280 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- MAGEA10 | c.894G>A p.W298* | Nonsense Mutation (SNP) | VAF 24/167 reads (14%) | called by muse, mutect2, varscan2
- MAGEA12 | c.295C>A p.P99T | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- MAGEA12 | c.296C>A p.P99H | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, varscan2
- MED12L | c.1506C>A p.N502K | Missense Mutation (SNP) | VAF 15/215 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.109); called by muse, mutect2
- MGAM2 | c.4037C>A p.A1346D | Missense Mutation (SNP) | VAF 34/392 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); called by muse, mutect2
- MROH2B | c.4563G>C p.R1521S | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- MRPS33 | c.72G>T p.R24S | Missense Mutation (SNP) | VAF 184/985 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- MSTN | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 47/277 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MTUS2 | c.2179C>A p.Q727K | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- MUC16 | c.38254A>T p.R12752* | Nonsense Mutation (SNP) | VAF 138/676 reads (20%) | called by muse, varscan2
- MUC16 | c.8528C>A p.T2843K | Missense Mutation (SNP) | VAF 55/202 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- MYBPH | c.869C>A p.P290H | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYLK3 | c.2430C>A p.N810K | Missense Mutation (SNP) | VAF 37/314 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- NAGLU | c.716C>T p.T239I | Missense Mutation (SNP) | VAF 59/562 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NCKAP5 | c.5641C>A p.L1881M | Missense Mutation (SNP) | VAF 63/370 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- NCKAP5 | c.1258G>C p.V420L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NEK1 | c.1065G>T p.R355S | Missense Mutation (SNP) | VAF 51/407 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.024); called by muse, mutect2
- NIM1K | c.872C>A p.P291Q | Missense Mutation (SNP) | VAF 30/305 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOL11 | c.1111G>C p.G371R | Missense Mutation (SNP) | VAF 36/445 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.386); called by muse, mutect2
- NPNT | c.1603-1G>T p.X535_splice | Splice Site (SNP) | VAF 14/152 reads (9%) | called by muse, mutect2
- NUF2 | c.1307G>T p.G436V | Missense Mutation (SNP) | VAF 84/463 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- OGFR | c.250del p.E84Nfs*11 | Frame Shift Del (DEL) | VAF 45/305 reads (15%) | called by mutect2, pindel, varscan2
- OR10G9 | c.68C>A p.A23D | Missense Mutation (SNP) | VAF 17/240 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2
- OR11H6 | c.222C>A p.H74Q | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- OR13C3 | c.382G>T p.A128S | Missense Mutation (SNP) | VAF 103/608 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- OR13C9 | c.734T>A p.L245Q | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- OR1E1 | c.913A>G p.I305V | Missense Mutation (SNP) | VAF 25/231 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR2T8 | c.602G>T p.C201F | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- OR4A47 | c.47C>A p.T16K | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- OR4C6 | c.43C>A p.L15I | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- OR5D13 | c.764G>A p.G255E | Missense Mutation (SNP) | VAF 19/201 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); called by muse, mutect2
- OR5H1 | c.638_639insA p.I214Yfs*18 | Frame Shift Ins (INS) | VAF 64/331 reads (19%) | called by mutect2, pindel, varscan2
- PADI4 | c.1918C>A p.H640N | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- PAGE1 | c.259C>G p.R87G | Missense Mutation (SNP) | VAF 42/182 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.171); called by muse, mutect2
- PAK5 | c.2084T>A p.L695H | Missense Mutation (SNP) | VAF 39/386 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- PAPPA2 | c.4394G>T p.G1465V | Missense Mutation (SNP) | VAF 19/330 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); called by muse, mutect2
- PARD3B | c.3383G>T p.R1128L (on ENST00000406610 / NM_001302769.2; = p.R1059L on NM_057177.7) | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT tolerated (0.69); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- PAXIP1 | c.520A>T p.T174S | Missense Mutation (SNP) | VAF 24/282 reads (9%) | SIFT tolerated (0.83); PolyPhen benign (0.038); called by muse, mutect2
- PCDH7 | c.2467G>T p.D823Y | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDH7 | c.2468A>G p.D823G | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHB11 | c.1915A>T p.R639W | Missense Mutation (SNP) | VAF 27/261 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCDHB6 | c.410T>A p.M137K | Missense Mutation (SNP) | VAF 87/434 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- PDZD2 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 44/364 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PEG3 | c.4031G>A p.S1344N | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PEG3 | c.4030A>T p.S1344C | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- PHGR1 | c.52C>A p.P18T | Missense Mutation (SNP) | VAF 24/119 reads (20%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PKHD1L1 | c.11396G>A p.G3799D | Missense Mutation (SNP) | VAF 12/165 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- PLBD2 | c.1645G>T p.A549S | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- PLCB4 | c.2928G>T p.E976D | Missense Mutation (SNP) | VAF 67/332 reads (20%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.931); called by muse, varscan2
- PLD1 | c.2184T>A p.H728Q | Missense Mutation (SNP) | VAF 32/522 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2
- PLEK | c.312A>C p.E104D | Missense Mutation (SNP) | VAF 47/418 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLEKHA5 | c.2890A>T p.R964* | Nonsense Mutation (SNP) | VAF 80/482 reads (17%) | called by muse, mutect2, varscan2
- PLXNA4 | c.1023G>T p.K341N | Missense Mutation (SNP) | VAF 25/274 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2
- POTEF | c.353del p.G118Afs*49 | Frame Shift Del (DEL) | VAF 37/327 reads (11%) | called by mutect2, pindel, varscan2
- PPFIA2 | c.2228C>A p.T743K | Missense Mutation (SNP) | VAF 98/605 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PPM1L | c.983C>A p.A328D | Missense Mutation (SNP) | VAF 39/678 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PPP4R3C | c.2150C>A p.P717Q | Missense Mutation (SNP) | VAF 92/441 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- PRAMEF14 | c.703C>A p.R235S | Missense Mutation (SNP) | VAF 113/1022 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PRDM9 | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 66/722 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PRKAR2A | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- PRKAR2B | c.975G>T p.M325I | Missense Mutation (SNP) | VAF 39/211 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- PRR23A | c.302C>A p.P101Q | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- PSG3 | c.878G>T p.R293M | Missense Mutation (SNP) | VAF 94/1461 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- PSG9 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 75/423 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- RAB3GAP2 | c.3259A>T p.R1087W | Missense Mutation (SNP) | VAF 68/674 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- RACK1 | c.126G>T p.M42I | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- RALYL | c.683C>A p.A228E | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.036); called by muse, mutect2
- RASGRP4 | c.1528C>A p.R510S | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- REV3L | c.8611G>C p.E2871Q | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- RNF180 | c.237G>T p.Q79H | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- RNF8 | c.826C>T p.Q276* | Nonsense Mutation (SNP) | VAF 60/508 reads (12%) | called by muse, mutect2, varscan2
- ROBO2 | c.2488C>T p.P830S | Missense Mutation (SNP) | VAF 87/527 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPS6KA6 | c.1489A>T p.T497S | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.618); called by muse, mutect2, varscan2
- RSPO2 | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 56/792 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.082); called by muse, mutect2
- RYR1 | c.1822T>C p.C608R | Missense Mutation (SNP) | VAF 134/990 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCN3A | c.3476C>G p.P1159R | Missense Mutation (SNP) | VAF 149/1075 reads (14%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- SCN5A | c.703+1G>T p.X235_splice | Splice Site (SNP) | VAF 19/156 reads (12%) | called by muse, mutect2, varscan2
- SCN9A | c.517G>T p.A173S | Missense Mutation (SNP) | VAF 61/545 reads (11%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SCPEP1 | c.313T>A p.W105R | Missense Mutation (SNP) | VAF 60/348 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEL1L2 | c.210A>T p.K70N | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- SERPINA10 | c.488G>T p.G163V | Missense Mutation (SNP) | VAF 54/504 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SHLD1 | c.12G>T p.R4S | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2
- SLC12A3 | c.503T>A p.I168N | Missense Mutation (SNP) | VAF 56/333 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC34A3 | c.289T>A p.F97I | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- SLC39A8 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 55/298 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC5A11 | c.952C>A p.L318M | Missense Mutation (SNP) | VAF 34/247 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLF1 | c.2289C>G p.D763E | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SLFN11 | c.2037C>A p.D679E | Missense Mutation (SNP) | VAF 126/879 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- SLITRK3 | c.661G>T p.G221C | Missense Mutation (SNP) | VAF 28/329 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SPHKAP | c.33-1G>T p.X11_splice | Splice Site (SNP) | VAF 33/284 reads (12%) | called by muse, mutect2, varscan2
- SSBP3 | c.629G>T p.G210V (on ENST00000371320 / NM_145716.4; = p.G190V on NM_018070.5) | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.042); called by muse, mutect2
- SSH2 | c.4051G>A p.G1351S | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- SSX5 | c.458dup p.T154Dfs*17 (on ENST00000347757 / NM_175723.1; = p.T195Dfs*17 on NM_021015.4) | Frame Shift Ins (INS) | VAF 33/153 reads (22%) | called by mutect2, pindel, varscan2
- SVOP | c.355A>G p.S119G | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- SYNE1 | c.743C>G p.T248R (on ENST00000367255 / NM_182961.4; = p.T255R on NM_033071.3) | Missense Mutation (SNP) | VAF 115/578 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TAOK1 | c.1664A>G p.Q555R | Missense Mutation (SNP) | VAF 10/282 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); called by muse, mutect2
- TDRD10 | c.-27_-25del | Splice Site (DEL) | VAF 28/318 reads (9%) | called by mutect2, pindel
- TDRD6 | c.2589G>T p.K863N | Missense Mutation (SNP) | VAF 11/294 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.03); called by muse, mutect2
- TEDDM1 | c.681C>G p.F227L | Missense Mutation (SNP) | VAF 64/981 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2
- TFEC | c.450A>C p.R150S | Missense Mutation (SNP) | VAF 20/293 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.378); called by muse, mutect2
- TGFBR3 | c.1696G>C p.E566Q | Missense Mutation (SNP) | VAF 64/1082 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.077); called by muse, mutect2
- TGFBRAP1 | c.1489C>T p.H497Y | Missense Mutation (SNP) | VAF 49/531 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.105); called by muse, mutect2
- TIGD3 | c.979dup p.S327Ffs*53 | Frame Shift Ins (INS) | VAF 14/72 reads (19%) | called by mutect2, pindel, varscan2
- TLX3 | c.292G>A p.G98R | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2
- TMEM160 | c.440T>A p.L147Q | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMPRSS15 | c.1222G>C p.G408R | Missense Mutation (SNP) | VAF 145/723 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TNFAIP1 | c.74T>A p.L25* | Nonsense Mutation (SNP) | VAF 23/122 reads (19%) | called by muse, mutect2, varscan2
- TPTE | c.1003G>T p.A335S (on ENST00000618007 / NM_199261.4; = p.A317S on NM_199259.4) | Missense Mutation (SNP) | VAF 54/955 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2
- TRHDE | c.1225T>C p.W409R | Missense Mutation (SNP) | VAF 82/808 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRIM48 | c.221C>A p.T74K | Missense Mutation (SNP) | VAF 151/739 reads (20%) | SIFT tolerated (0.91); PolyPhen benign (0.211); called by muse, varscan2
- TRIM67 | c.434C>A p.A145D | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.093); called by mutect2, varscan2
- TRPV5 | c.2122A>C p.T708P | Missense Mutation (SNP) | VAF 26/336 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- TSHR | c.2134C>A p.P712T | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTC17 | c.2441C>G p.P814R | Missense Mutation (SNP) | VAF 41/206 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTC23L | c.50G>C p.W17S | Missense Mutation (SNP) | VAF 27/412 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TTLL10 | c.1240G>T p.G414C (on ENST00000379289 / NM_001130045.2; = p.G341C on NM_153254.3) | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); called by muse, mutect2
- TTLL7 | c.1571A>T p.K524M | Missense Mutation (SNP) | VAF 42/486 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2
- TTN | c.79627A>T p.S26543C (on ENST00000591111; = p.S19119C on NM_003319.4) | Missense Mutation (SNP) | VAF 9/72 reads (13%) | PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- TTN | c.68254C>A p.Q22752K (on ENST00000591111; = p.Q15328K on NM_003319.4) | Missense Mutation (SNP) | VAF 24/167 reads (14%) | PolyPhen benign (0.124); called by muse, mutect2, varscan2
- TTN | c.26584G>C p.A8862P (on ENST00000591111; = p.A7935P on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/280 reads (15%) | PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UMODL1 | c.2350A>G p.K784E (on ENST00000408910 / NM_001004416.2; = p.K912E on NM_173568.3) | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.275); called by muse, varscan2
- UPF2 | c.528G>C p.K176N | Missense Mutation (SNP) | VAF 80/426 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- UPP2 | c.455G>A p.G152E | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2
- URB2 | c.3724G>T p.D1242Y | Missense Mutation (SNP) | VAF 74/403 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- USHBP1 | c.494G>C p.G165A | Missense Mutation (SNP) | VAF 53/245 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- WASHC2A | c.1003G>C p.D335H | Missense Mutation (SNP) | VAF 61/458 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- WDR49 | c.1321G>C p.D441H (on ENST00000308378 / NM_001366158.1; = p.D782H on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- XPO1 | c.3054C>A p.F1018L | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- XPR1 | c.1235A>G p.Y412C | Missense Mutation (SNP) | VAF 42/591 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- ZFP42 | c.722G>C p.G241A | Missense Mutation (SNP) | VAF 25/398 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- ZNF226 | c.511G>T p.D171Y | Missense Mutation (SNP) | VAF 77/322 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- ZNF418 | c.660A>T p.Q220H | Missense Mutation (SNP) | VAF 59/187 reads (32%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.948); called by muse, varscan2
- ZP4 | c.673C>A p.P225T | Missense Mutation (SNP) | VAF 24/288 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZW10 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 40/190 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ABCB5 | c.2097T>C p.S699= (on ENST00000404938 / NM_001163941.2; = p.S254= on NM_178559.6) | Silent (SNP) | VAF 22/178 reads (12%) | called by muse, mutect2, varscan2
- ACTN2 | c.627A>T p.I209= | Silent (SNP) | VAF 104/677 reads (15%) | called by muse, mutect2, varscan2
- ADAMTS2 | c.1338C>T p.F446= | Silent (SNP) | VAF 12/136 reads (9%) | called by muse, mutect2
- ADAMTS20 | c.5499C>A p.A1833= | Silent (SNP) | VAF 40/528 reads (8%) | called by muse, mutect2
- ADCY2 | c.501C>T p.S167= | Silent (SNP) | VAF 27/339 reads (8%) | called by muse, mutect2
- AICDA | c.354C>T p.D118= | Silent (SNP) | VAF 23/316 reads (7%) | catalogued as COSV99984344; called by muse, mutect2
- ANKRD55 | c.384C>T p.R128= | Silent (SNP) | VAF 55/410 reads (13%) | called by muse, mutect2, varscan2
- ANO8 | c.1374C>T p.F458= | Silent (SNP) | VAF 15/122 reads (12%) | catalogued as COSV50197500; called by muse, mutect2, varscan2
- ASL | c.531C>T p.A177= | Silent (SNP) | VAF 19/166 reads (11%) | catalogued as rs201974677; called by muse, mutect2, varscan2
- ASXL3 | c.4461G>T p.L1487= | Silent (SNP) | VAF 29/136 reads (21%) | called by muse, mutect2, varscan2
- BRAT1 | c.375G>A p.Q125= | Silent (SNP) | VAF 28/110 reads (25%) | called by muse, mutect2, varscan2
- CACNG8 | c.237C>A p.P79= | Silent (SNP) | VAF 4/16 reads (25%) | called by mutect2, varscan2
- CDK5 | c.465C>T p.V155= | Silent (SNP) | VAF 20/319 reads (6%) | called by muse, mutect2
- CLRN1 | c.336C>T p.T112= (on ENST00000327047 / NM_174878.3; = p.T36= on NM_052995.2) | Silent (SNP) | VAF 187/707 reads (26%) | catalogued as rs565400473; called by muse, mutect2, varscan2
- CNGB3 | c.276A>T p.A92= | Silent (SNP) | VAF 63/1072 reads (6%) | called by muse, mutect2
- COL5A2 | c.3144A>T p.P1048= | Silent (SNP) | VAF 20/538 reads (4%) | catalogued as COSV66410664; called by muse, mutect2
- COL6A6 | c.3474G>T p.V1158= | Silent (SNP) | VAF 68/260 reads (26%) | called by muse, mutect2, varscan2
- CYP4F12 | c.654C>A p.P218= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs768037263; called by muse, mutect2, varscan2
- DCAF4L2 | c.321G>T p.L107= | Silent (SNP) | VAF 8/150 reads (5%) | called by muse, mutect2
- DPRX | c.555T>C p.S185= | Silent (SNP) | VAF 16/47 reads (34%) | called by muse, mutect2, varscan2
- EEFSEC | c.942G>T p.A314= | Silent (SNP) | VAF 60/265 reads (23%) | catalogued as COSV54621385; called by muse, mutect2, varscan2
- EFNA3 | c.321C>A p.R107= | Silent (SNP) | VAF 29/195 reads (15%) | called by muse, mutect2, varscan2
- FAM135B | c.645G>T p.G215= | Silent (SNP) | VAF 28/221 reads (13%) | catalogued as COSV52713234; called by muse, mutect2, varscan2
- FBXL7 | c.657C>G p.V219= | Silent (SNP) | VAF 23/245 reads (9%) | catalogued as rs1303108476; called by muse, mutect2
- FCGR2B | c.147G>A p.K49= | Silent (SNP) | VAF 24/532 reads (5%) | catalogued as rs1353673206, COSV52681629; called by muse, mutect2
- FLNC | c.723G>T p.V241= | Silent (SNP) | VAF 34/463 reads (7%) | called by muse, mutect2
- FSCN3 | c.1395C>T p.L465= | Silent (SNP) | VAF 15/244 reads (6%) | catalogued as rs1363000096; called by muse, mutect2
- GLI4 | c.42G>A p.P14= | Silent (SNP) | VAF 41/197 reads (21%) | catalogued as rs747024865; called by muse, mutect2, varscan2
- GPRC5B | c.915C>A p.P305= | Silent (SNP) | VAF 74/319 reads (23%) | called by muse, mutect2, varscan2
- HCK | c.615C>T p.N205= | Silent (SNP) | VAF 16/308 reads (5%) | catalogued as rs986847689, COSV52940528; called by muse, mutect2
- HK2 | c.2115G>T p.V705= | Silent (SNP) | VAF 56/274 reads (20%) | called by muse, mutect2, varscan2
- HOXD12 | c.480T>A p.P160= | Silent (SNP) | VAF 10/97 reads (10%) | called by muse, mutect2, varscan2
- HS3ST3A1 | c.852C>T p.S284= | Silent (SNP) | VAF 32/230 reads (14%) | catalogued as rs772168174, COSV99404470; called by muse, mutect2, varscan2
- ITFG1 | c.546G>A p.Q182= | Silent (SNP) | VAF 33/236 reads (14%) | called by muse, mutect2, varscan2
- KCNA10 | c.687C>A p.S229= | Silent (SNP) | VAF 17/117 reads (15%) | called by muse, mutect2, varscan2
- KPRP | c.1440C>A p.P480= | Silent (SNP) | VAF 19/197 reads (10%) | called by muse, mutect2, varscan2
- KRT5 | c.1110G>A p.Q370= | Silent (SNP) | VAF 50/600 reads (8%) | catalogued as rs748377756; called by muse, mutect2
- LHX6 | c.981C>T p.C327= (on ENST00000373755 / NM_001242334.2; = p.C356= on NM_014368.5) | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as rs202183953, COSV61344225; called by muse, varscan2
- LMBR1 | c.42C>T p.F14= | Silent (SNP) | VAF 14/176 reads (8%) | called by muse, mutect2
- LRP1B | c.9180C>A p.I3060= | Silent (SNP) | VAF 18/176 reads (10%) | catalogued as rs774022861, COSV101256803, COSV67192452; called by muse, varscan2
- LRP1B | c.288G>T p.L96= | Silent (SNP) | VAF 62/447 reads (14%) | called by muse, mutect2, varscan2
- MAPK11 | c.186G>C p.L62= | Silent (SNP) | VAF 31/164 reads (19%) | called by muse, mutect2, varscan2
- MMP9 | c.1035G>A p.E345= | Silent (SNP) | VAF 9/81 reads (11%) | catalogued as rs777085112; called by muse, mutect2, varscan2
- MOGAT2 | c.558G>A p.G186= | Silent (SNP) | VAF 14/160 reads (9%) | called by muse, mutect2
- MYO3A | c.2436G>A p.L812= | Silent (SNP) | VAF 27/419 reads (6%) | catalogued as COSV56347119; called by muse, mutect2
- NDST1 | c.67C>T p.L23= | Silent (SNP) | VAF 10/59 reads (17%) | called by muse, mutect2, varscan2
- NMBR | c.306G>T p.S102= | Silent (SNP) | VAF 40/233 reads (17%) | catalogued as rs544695044, COSV57801965; called by muse, mutect2, varscan2
- NPAS4 | c.771G>A p.E257= | Silent (SNP) | VAF 38/499 reads (8%) | called by muse, mutect2
- OR2T12 | c.90G>T p.L30= | Silent (SNP) | VAF 47/228 reads (21%) | catalogued as COSV100527868; called by muse, mutect2, varscan2
- OR5T1 | c.57T>C p.T19= | Silent (SNP) | VAF 4/57 reads (7%) | called by muse, mutect2
- OR6F1 | c.342C>A p.L114= | Silent (SNP) | VAF 34/248 reads (14%) | called by muse, mutect2, varscan2
- OSGIN2 | c.21T>G p.T7= | Silent (SNP) | VAF 27/307 reads (9%) | called by muse, mutect2
- PALLD | c.2628C>T p.R876= (on ENST00000505667 / NM_001166108.2; = p.R859= on NM_016081.4) | Silent (SNP) | VAF 60/690 reads (9%) | catalogued as COSV99825017; called by muse, mutect2
- PAX7 | c.876C>T p.F292= | Silent (SNP) | VAF 11/77 reads (14%) | called by muse, mutect2, varscan2
- PCDHA8 | c.1056G>T p.L352= | Silent (SNP) | VAF 47/234 reads (20%) | called by muse, mutect2, varscan2
- PCDHAC2 | c.2169C>T p.I723= | Silent (SNP) | VAF 43/365 reads (12%) | catalogued as COSV53836896; called by muse, mutect2, varscan2
- PDE3A | c.1665C>A p.A555= | Silent (SNP) | VAF 50/740 reads (7%) | called by muse, mutect2
- PIEZO1 | c.894C>T p.S298= | Silent (SNP) | VAF 28/152 reads (18%) | catalogued as rs1420327605; called by muse, mutect2, varscan2
- PLCB4 | c.1293C>A p.L431= | Silent (SNP) | VAF 14/206 reads (7%) | called by muse, mutect2
- PLPPR2 | c.501G>C p.T167= | Silent (SNP) | VAF 45/225 reads (20%) | called by muse, mutect2, varscan2
- PRSS58 | c.465G>A p.V155= | Silent (SNP) | VAF 41/395 reads (10%) | called by muse, mutect2, varscan2
- PSG3 | c.879G>A p.R293= | Silent (SNP) | VAF 96/1460 reads (7%) | called by muse, mutect2
- RHOBTB3 | c.870C>T p.P290= | Silent (SNP) | VAF 46/215 reads (21%) | called by muse, mutect2, varscan2
- RIMS2 | c.4686C>T p.S1562= (on ENST00000666250 / NM_001348490.2; = p.S1133= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 58/858 reads (7%) | called by muse, mutect2
- RIPOR3 | c.1347A>T p.P449= | Silent (SNP) | VAF 16/67 reads (24%) | called by muse, mutect2, varscan2
- RNF213 | c.1575G>T p.G525= | Silent (SNP) | VAF 12/322 reads (4%) | catalogued as COSV60629753; called by muse, mutect2
- RPRD2 | c.45G>T p.S15= | Silent (SNP) | VAF 30/286 reads (10%) | called by muse, mutect2, varscan2
- SHANK1 | c.4548G>T p.P1516= | Silent (SNP) | VAF 10/14 reads (71%) | called by mutect2, varscan2
- SLC39A4 | c.1599G>C p.V533= (on ENST00000301305 / NM_001374839.1; = p.V508= on NM_017767.3) | Silent (SNP) | VAF 12/206 reads (6%) | called by muse, mutect2
- SLC45A2 | c.1521G>C p.V507= | Silent (SNP) | VAF 59/552 reads (11%) | catalogued as rs1325153463; called by muse, mutect2, varscan2
- SLC9A3 | c.369C>T p.I123= | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as rs144657077; called by muse, mutect2, varscan2
- SLITRK5 | c.210C>A p.I70= | Silent (SNP) | VAF 35/270 reads (13%) | catalogued as COSV61523608; called by muse, mutect2, varscan2
- SRGAP1 | c.1158G>T p.T386= | Silent (SNP) | VAF 62/320 reads (19%) | called by muse, varscan2
- STK31 | c.699C>T p.L233= | Silent (SNP) | VAF 20/320 reads (6%) | called by muse, mutect2
- TGFBI | c.1089G>A p.V363= | Silent (SNP) | VAF 36/199 reads (18%) | catalogued as rs760069077; called by muse, mutect2, varscan2
- TIMD4 | c.780C>A p.L260= | Silent (SNP) | VAF 66/280 reads (24%) | called by muse, mutect2, varscan2
- TNS4 | c.2010C>A p.I670= | Silent (SNP) | VAF 17/92 reads (18%) | called by muse, mutect2, varscan2
- TRPM1 | c.2283C>A p.I761= | Silent (SNP) | VAF 32/334 reads (10%) | called by muse, mutect2
- TTYH3 | c.975G>T p.V325= | Silent (SNP) | VAF 37/187 reads (20%) | called by muse, mutect2, varscan2
- UNC5D | c.1833C>A p.I611= | Silent (SNP) | VAF 67/324 reads (21%) | catalogued as COSV54811377; called by muse, mutect2, varscan2
- UNC79 | c.3076C>T p.L1026= (on ENST00000393151 / NM_001346218.2; = p.L849= on NM_020818.5) | Silent (SNP) | VAF 46/163 reads (28%) | called by muse, mutect2, varscan2
- VARS1 | c.546G>T p.R182= | Silent (SNP) | VAF 52/236 reads (22%) | called by muse, mutect2, varscan2
- VPS13B | c.9867A>C p.S3289= | Silent (SNP) | VAF 42/592 reads (7%) | called by muse, mutect2
- WFDC1 | c.111G>C p.R37= | Silent (SNP) | VAF 19/154 reads (12%) | called by muse, mutect2, varscan2
- WFS1 | c.2214C>A p.A738= | Silent (SNP) | VAF 10/53 reads (19%) | called by muse, mutect2, varscan2
- YTHDF1 | c.918A>T p.P306= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as rs1446425004; called by muse, mutect2
- ZMYND8 | c.3093C>T p.C1031= (on ENST00000311275 / NM_001363741.2; = p.C1005= on NM_012408.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 33/504 reads (7%) | catalogued as COSV53682632; called by muse, mutect2
- ZNF423 | c.1140C>A p.P380= (on ENST00000563137 / NM_001379286.1; = p.P372= on NM_015069.4) | Silent (SNP) | VAF 20/114 reads (18%) | catalogued as COSV52204472; called by muse, mutect2, varscan2
- ZNF830 | c.549G>T p.P183= | Silent (SNP) | VAF 29/188 reads (15%) | catalogued as rs746430524; called by muse, mutect2, varscan2
- AC064807.1 | n.2531G>T | RNA (SNP) | VAF 19/98 reads (19%) | called by muse, mutect2, varscan2
- AC073264.3 | chr7:143620959 C>A | 5'Flank (SNP) | VAF 7/26 reads (27%) | called by muse, mutect2, varscan2
- AC093791.1 | n.454C>A | RNA (SNP) | VAF 8/45 reads (18%) | called by muse, mutect2, varscan2
- AC133561.1 | n.1344G>T | RNA (SNP) | VAF 14/40 reads (35%) | called by mutect2, varscan2
- AC136604.1 | chr5:179652311 G>T | 3'Flank (SNP) | VAF 94/488 reads (19%) | called by muse, varscan2
- ACSM2B | c.895-1338C>A | Intron (SNP) | VAF 49/336 reads (15%) | called by muse, mutect2, varscan2
- ANKRD33 | c.664+29C>A | Intron (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2
- BOC | c.-112G>A | 5'UTR (SNP) | VAF 43/237 reads (18%) | called by muse, mutect2, varscan2
- BTN2A3P | n.1448-462G>A | Intron (SNP) | VAF 11/178 reads (6%) | called by muse, mutect2
- C12orf42 | c.259+789C>A | Intron (SNP) | VAF 22/456 reads (5%) | catalogued as COSV59391963; called by muse, mutect2
- CLASP2 | c.2071+174A>C | Intron (SNP) | VAF 38/186 reads (20%) | called by muse, mutect2, varscan2
- CLLU1 | chr12:92422562 G>T | 5'Flank (SNP) | VAF 68/379 reads (18%) | called by muse, mutect2, varscan2
- CPED1 | c.2311-4574G>C | Intron (SNP) | VAF 122/417 reads (29%) | called by muse, mutect2, varscan2
- DCHS2 | n.5663T>C | RNA (SNP) | VAF 41/494 reads (8%) | called by muse, mutect2
- DDX41 | c.*375C>A | 3'UTR (SNP) | VAF 62/329 reads (19%) | catalogued as rs768748580; called by muse, mutect2, varscan2
- DEFB130C | chr11:71865852 C>A | 3'Flank (SNP) | VAF 12/168 reads (7%) | called by muse, mutect2
- DIO3 | chr14:101557655 G>T | 5'Flank (SNP) | VAF 58/273 reads (21%) | called by muse, mutect2, varscan2
- EIPR1 | c.516+5418G>T | Intron (SNP) | VAF 87/350 reads (25%) | called by muse, mutect2, varscan2
- EYS | c.1767-7308G>T | Intron (SNP) | VAF 124/599 reads (21%) | called by muse, mutect2, varscan2
- EYS | c.1767-7875G>T | Intron (SNP) | VAF 52/347 reads (15%) | called by muse, mutect2, varscan2
- FRMD8P1 | n.252G>T | RNA (SNP) | VAF 14/78 reads (18%) | called by muse, mutect2, varscan2
- FUT7 | chr9:137034990 A>T | 5'Flank (SNP) | VAF 14/55 reads (25%) | catalogued as rs1250304980; called by muse, mutect2, varscan2
- GDAP1 | c.*2169T>A | 3'UTR (SNP) | VAF 30/178 reads (17%) | called by muse, mutect2, varscan2
- HGF | c.89-34T>C | Intron (SNP) | VAF 12/121 reads (10%) | called by muse, mutect2, varscan2
- ITFG1 | c.560+1005G>T | Intron (SNP) | VAF 24/180 reads (13%) | called by muse, mutect2, varscan2
- MIR510 | n.48T>C | RNA (SNP) | VAF 15/72 reads (21%) | catalogued as rs1041712363, CR096698; called by muse, mutect2, varscan2
- MMP16 | c.1222+5132C>A | Intron (SNP) | VAF 33/318 reads (10%) | catalogued as COSV54186069, COSV54189431; called by muse, mutect2, varscan2
- MYL3 | chr3:46834004 del G | 3'Flank (DEL) | VAF 6/20 reads (30%) | called by mutect2, pindel
- PDGFRA | c.2323+18C>G | Intron (SNP) | VAF 28/266 reads (11%) | called by muse, mutect2, varscan2
- PDLIM3 | c.94-25C>A | Intron (SNP) | VAF 40/736 reads (5%) | called by muse, mutect2
- PLCE1 | c.1810-48C>T | Intron (SNP) | VAF 16/268 reads (6%) | called by muse, mutect2
- PLCZ1 | c.949+9G>A | Intron (SNP) | VAF 38/391 reads (10%) | catalogued as COSV56852648; called by muse, varscan2
- PRICKLE2 | c.564+16G>A | Intron (SNP) | VAF 46/312 reads (15%) | catalogued as rs746187709; called by muse, mutect2, varscan2
- RPS17 | c.-13A>G | 5'UTR (SNP) | VAF 91/519 reads (18%) | called by muse, mutect2, varscan2
- SH2D6 | n.329+15G>A | Intron (SNP) | VAF 36/155 reads (23%) | called by muse, mutect2, varscan2
- SLC22A16 | c.1522-295C>T | Intron (SNP) | VAF 33/280 reads (12%) | catalogued as rs899890341; called by muse, mutect2, varscan2
- SLC25A11 | c.248+16G>A | Intron (SNP) | VAF 43/337 reads (13%) | called by muse, mutect2, varscan2
- SNX29 | c.2038-34690G>T | Intron (SNP) | VAF 23/190 reads (12%) | called by muse, mutect2, varscan2
- SPATA8 | n.807G>A | RNA (SNP) | VAF 15/112 reads (13%) | called by muse, mutect2, varscan2
- SRL | c.62-2335C>A | Intron (SNP) | VAF 8/29 reads (28%) | called by muse, mutect2, varscan2
- TMEM44 | c.924+535G>T | Intron (SNP) | VAF 26/164 reads (16%) | called by muse, mutect2, varscan2
- TMEM52 | c.171-44C>T | Intron (SNP) | VAF 32/212 reads (15%) | catalogued as rs183010571; called by muse, mutect2, varscan2
- TRBV2 | c.-21C>A | 5'UTR (SNP) | VAF 79/314 reads (25%) | called by muse, mutect2, varscan2
- TTC26 | c.792+23G>T | Intron (SNP) | VAF 19/160 reads (12%) | called by muse, mutect2, varscan2
- WASHC5 | c.-24A>G | 5'UTR (SNP) | VAF 44/594 reads (7%) | called by muse, mutect2
- ZNF568 | c.*15T>C | 3'UTR (SNP) | VAF 38/209 reads (18%) | called by muse, mutect2, varscan2
